Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A014, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A014-01A (Primary Tumor).

Sample ID #

Diagnosis:

Resected section of colon (rectosigmoid) with an ulcerated rectal carcinoma histologically characterized as a poorly differentiated colorectal adenocarcinoma, extending a maximum of 1.7 cm to the aboral resection margin, and measuring a maximum of 3 cm at the widest point. Invasive spreading of the tumor to the muscularis propria. Sigma with individual pseudodiverticula and mild, chronically scarring peridiverticulitis.

Tumor-free oral and aboral resection margin.

15 local lymph nodes are tumor-free with uncharacteristically reactive changes.

Stage of tumor: pT2 pN0 (0/15) L0, V0; G3 R0.

1CD-0-3

Adenocarcinoma, NOS 8140/3

Site: rectum C20.9 for 3/31/11

Source: NCI Genomic Data Commons file d422e616-d6ed-40b7-bfeb-c9113cd39244 (TCGA-AG-A014.E7797640-A527-49D6-800D-F3F300D173E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).